Gene-level copy-number profile of tumor specimen TCGA-P3-A6SW-01A from TCGA case TCGA-P3-A6SW, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 50.7 years (18,536 days).
Specimen TCGA-P3-A6SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.4a1a6c1f-92d9-47d6-bf54-9b70b4cac347.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A6SW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d3a7769f-5d46-4b53-b928-9f892145cea3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 6,161; copy number 2: 44,076; copy number 3: 6,096; copy number 4: 1,527; copy number 5: 1,800; copy number 6: 57; copy number 7: 45; copy number 8: 4; copy number 10: 31; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A6SW-01A-11D-A34I-01): tumor purity 0.32, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,947 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5 (broad region; genes not listed).
- chr9:14,475–10,612,723, 147 genes, copy number 6–22 (within-gene range 2–22) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,783. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
